Somatic mutation profile of tumor specimen MMRF_2213_1_BM_CD138pos (aliquot MMRF_2213_1_BM_CD138pos_T1_KHS5U_L08718) from MMRF case MMRF_2213, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,124 days).
Specimen MMRF_2213_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24bbc4eb-94a7-4949-87a3-72f57a87edb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2213_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2213_1_PB_Whole_C3_KHS5U_L08717; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b278d18e-e033-4cc0-9165-7375625ddbb9

The open-access MAF lists 144 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 49, Missense Mutation 42, Intron 20, Silent 11, RNA 5, 5'UTR 4, 5'Flank 4, Frame Shift Del 3, Splice Region 1, Nonsense Mutation 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1072dup p.A358Gfs*30 (on ENST00000372530 / NM_001198934.2; = p.A315Gfs*30 on NM_033450.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 146/269 reads (54%) | catalogued as rs765263114; called by mutect2, pindel, varscan2
- ALMS1 | c.2993T>A p.V998E | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs1480245107; called by muse, mutect2, varscan2
- ARAP3 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 123/455 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs976476927, COSV53348668; called by muse, mutect2, varscan2
- CFAP46 | c.7196T>A p.I2399N | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs1490234242; called by muse, mutect2, varscan2
- CSMD2 | c.4670C>T p.S1557L | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs1557657529; called by muse, mutect2, varscan2
- ETS1 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60092228; called by muse, mutect2, varscan2
- FLG2 | c.2838del p.F946Lfs*281 | Frame Shift Del (DEL) | VAF 150/478 reads (31%) | catalogued as rs1157006689; called by mutect2, varscan2
- GALNT2 | c.1134C>A p.A378= | Splice Region (SNP) | VAF 37/101 reads (37%) | catalogued as rs1480752948; called by muse, mutect2, varscan2
- IGHD2-2 | c.17A>C p.Y6S | Missense Mutation (SNP) | VAF 9/10 reads (90%) | catalogued as rs535073705; called by muse, mutect2
- IGLV3-1 | c.132T>G p.D44E | Missense Mutation (SNP) | VAF 52/52 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs373697673; called by muse, varscan2
- ITGB5 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs534537083; called by muse, mutect2, varscan2
- LHCGR | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV54293965; called by muse, mutect2, varscan2
- MTTP | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as COSV55510320, COSV99645362; called by muse, mutect2, varscan2
- NAV3 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV57071559; called by muse, mutect2, varscan2
- NRAS | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV54738004, COSV54746465; called by muse, mutect2, varscan2
- NRK | c.3223C>T p.L1075F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99688561; called by muse, mutect2, varscan2
- PCDHB11 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.108); catalogued as rs782269368, COSV53377326; called by muse, mutect2, varscan2
- SCN8A | c.5672G>A p.R1891H | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1555231135, COSV100633857; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTA1 | c.5674G>C p.E1892Q | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.156); catalogued as COSV63751177; called by muse, mutect2, varscan2
- TENM3 | c.7729G>A p.V2577M | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs147863067; called by muse, mutect2, varscan2
- UGT1A5 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs369417360, COSV59397276; called by muse, mutect2, varscan2
- ZFP28 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs774922640, COSV56737726; called by muse, mutect2, varscan2
- AGBL4 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2
- CD3G | c.295_299del p.V99Lfs*9 | Frame Shift Del (DEL) | VAF 42/106 reads (40%) | called by mutect2, varscan2
- CDH9 | c.1629A>T p.K543N | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CLTCL1 | c.4003C>A p.H1335N | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DPM2 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- FMN2 | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- GINS4 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- GNG2 | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 122/297 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- GTF3C1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- H2BC9 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- HMGCR | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- ING1 | c.922_927del p.N308_H309del | In Frame Del (DEL) | VAF 57/61 reads (93%) | called by mutect2, pindel, varscan2
- KIF19 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- LONP2 | c.2475C>G p.S825R | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC14B | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, varscan2
- LTN1 | c.3859T>A p.F1287I | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- NCOR2 | c.4649T>A p.F1550Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.754); called by muse, mutect2
- PCNT | c.2102A>G p.N701S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.38); called by muse, mutect2
- PRDM8 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SMG7 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); called by muse, mutect2
- TDRP | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- THOC3 | c.456T>A p.D152E | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TRAF3 | c.297+2T>G p.X99_splice | Splice Site (SNP) | VAF 81/87 reads (93%) | called by muse, mutect2, varscan2
- TUBG1 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TYRO3 | c.1689A>T p.E563D | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP32 | c.1715A>T p.H572L | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- XAB2 | c.1738T>C p.F580L | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF93 | c.291del p.V98* | Frame Shift Del (DEL) | VAF 46/181 reads (25%) | called by mutect2, varscan2
- AGRN | c.3792C>T p.A1264= | Silent (SNP) | VAF 43/45 reads (96%) | called by muse, mutect2, varscan2
- ASTN2 | c.1812G>C p.P604= (on ENST00000313400 / NM_001365069.1; = p.P553= on NM_014010.5) | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV57787097; called by muse, mutect2, varscan2
- CDH10 | c.594C>A p.V198= | Silent (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- CFAP46 | c.5958C>G p.G1986= | Silent (SNP) | VAF 8/178 reads (4%) | catalogued as COSV99584910; called by muse, mutect2
- HMGCLL1 | c.189T>C p.C63= | Silent (SNP) | VAF 39/136 reads (29%) | called by muse, mutect2, varscan2
- HSPB7 | c.339G>A p.A113= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs775935351, COSV61307927; called by muse, mutect2, varscan2
- QPCTL | c.681G>A p.A227= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs1378780559; called by muse, mutect2, varscan2
- SH3PXD2A | c.2532G>A p.S844= (on ENST00000369774 / NM_001365079.1; = p.S816= on NM_014631.2) | Silent (SNP) | VAF 230/232 reads (99%) | catalogued as rs779767127; called by muse, mutect2, varscan2
- SLC4A10 | c.906A>G p.K302= | Silent (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- TLE3 | c.129C>G p.L43= | Silent (SNP) | VAF 56/239 reads (23%) | called by muse, mutect2, varscan2
- ZEB2 | c.3279C>T p.R1093= | Silent (SNP) | VAF 85/145 reads (59%) | catalogued as COSV100356921; called by muse, mutect2, varscan2
- ACTR3 | c.540+80T>C | Intron (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
- AL033381.1 | n.728T>C | RNA (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2, varscan2
- AL359649.1 | n.423C>A | RNA (SNP) | VAF 10/10 reads (100%) | catalogued as rs1196021324; called by muse, mutect2, varscan2
- ALDH5A1 | c.*852A>T | 3'UTR (SNP) | VAF 52/190 reads (27%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38623981 C>T | 5'Flank (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- ANKRD46 | c.636+1184T>A | Intron (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- ANO1 | c.*510G>A | 3'UTR (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498382 C>G | 5'Flank (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- AP1G1 | c.-28T>C | 5'UTR (SNP) | VAF 33/74 reads (45%) | catalogued as rs1283707264; called by muse, mutect2, varscan2
- AP4E1 | c.*671C>T | 3'UTR (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- ARL10 | c.*9281T>C | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- ARL14EP | c.-63-965T>A | Intron (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- ASCC2 | c.541+42C>T | Intron (SNP) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- C1orf158 | c.-72A>G | 5'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- C9orf64 | c.*571C>G | 3'UTR (SNP) | VAF 35/96 reads (36%) | catalogued as rs950413757; called by muse, mutect2, varscan2
- CCDC40 | c.29+25G>T | Intron (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- CERK | c.*1754A>G | 3'UTR (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- CKAP4 | c.*1068A>C | 3'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, varscan2
- CLN8 | c.*5756C>T | 3'UTR (SNP) | VAF 75/139 reads (54%) | catalogued as rs959408289; called by muse, mutect2, varscan2
- CWH43 | c.-20C>T | 5'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- DCN | c.*608A>C | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- DCST1 | c.*51C>T | 3'UTR (SNP) | VAF 62/185 reads (34%) | called by muse, mutect2, varscan2
- DGKB | c.*223G>A | 3'UTR (SNP) | VAF 37/107 reads (35%) | called by muse, mutect2, varscan2
- DLG3 | c.*2184C>G | 3'UTR (SNP) | VAF 23/25 reads (92%) | called by muse, mutect2, varscan2
- DPP6 | c.244-141086C>T | Intron (SNP) | VAF 10/40 reads (25%) | called by muse, varscan2
- DTNA | c.1662+4075A>C | Intron (SNP) | VAF 36/128 reads (28%) | called by muse, mutect2, varscan2
- ELOVL6 | c.*2175_*2198del | 3'UTR (DEL) | VAF 21/108 reads (19%) | called by mutect2, pindel, varscan2
- EPHA7 | c.*603T>G | 3'UTR (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- EPHX1 | c.*118G>A | 3'UTR (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- FAM9B | c.29-87del | Intron (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel
- FANCG | c.84+9G>C | Intron (SNP) | VAF 63/202 reads (31%) | called by muse, mutect2, varscan2
- FBXO40 | c.*2637T>G | 3'UTR (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- FGF6 | c.*24G>T | 3'UTR (SNP) | VAF 50/91 reads (55%) | called by muse, mutect2, varscan2
- FOXP1 | c.*2428A>T | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- FRMD4B | c.501+50A>G | Intron (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- FRMD6 | c.1360+9A>T | Intron (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- GABRG1 | c.*2421T>G | 3'UTR (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- GADD45B | c.147-58G>A | Intron (SNP) | VAF 42/65 reads (65%) | called by muse, mutect2, varscan2
- HECTD2 | c.*1516G>T | 3'UTR (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- HMGN3 | c.*354G>A | 3'UTR (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- HNRNPA0 | c.*976T>C | 3'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- ITIH5 | c.653-2214A>T | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2
- LAMP2 | c.1093+2972T>A | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- LONRF1 | c.*1133T>G | 3'UTR (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- MC4R | c.*4G>C | 3'UTR (SNP) | VAF 111/407 reads (27%) | called by muse, mutect2, varscan2
- METTL1 | c.*134G>A | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- MIB1 | c.*529A>G | 3'UTR (SNP) | VAF 36/107 reads (34%) | called by muse, mutect2, varscan2
- MMP15 | c.*157T>G | 3'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- MOB1B | c.*454T>A | 3'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- MSNP1 | n.5C>T | RNA (SNP) | VAF 69/94 reads (73%) | called by muse, mutect2, varscan2
- MUC17 | c.*193G>T | 3'UTR (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- NECTIN1 | c.*2771G>C | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- NPAP1 | c.*1819G>A | 3'UTR (SNP) | VAF 12/37 reads (32%) | catalogued as COSV61507859; called by muse, mutect2, varscan2
- NR3C1 | c.*2864A>T | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- NUP93 | c.2220+44T>G | Intron (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- PAQR8 | c.*3242T>G | 3'UTR (SNP) | VAF 12/76 reads (16%) | catalogued as COSV62442800; called by muse, mutect2, varscan2
- PBX1 | c.*2457C>T | 3'UTR (SNP) | VAF 15/60 reads (25%) | catalogued as rs988822105; called by muse, mutect2, varscan2
- PDCD6IPP2 | n.596G>C | RNA (SNP) | VAF 48/209 reads (23%) | called by muse, varscan2
- PDCD6IPP2 | n.597C>A | RNA (SNP) | VAF 51/215 reads (24%) | called by muse, varscan2
- PDE1A | c.101+95434C>T | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- PDE3A | c.*1623A>T | 3'UTR (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- PHC3 | c.378+15T>A | Intron (SNP) | VAF 37/133 reads (28%) | catalogued as COSV71923574, COSV71923687; called by muse, varscan2
- SAMD4A | c.*3215A>T | 3'UTR (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- SEMA6A | c.*1659C>T | 3'UTR (SNP) | VAF 28/79 reads (35%) | catalogued as rs1561455242; called by muse, mutect2, varscan2
- SIAH1 | chr16:48365867 A>C | 5'Flank (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2
- SLA | c.*1700C>T | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- SLC9A8 | c.*3906C>A | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- SLCO4C1 | c.*251_*256delinsGA | 3'UTR (DEL) | VAF 4/38 reads (11%) | called by pindel, varscan2*
- SMARCD3 | c.*252T>G | 3'UTR (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- SMC1A | c.*506T>G | 3'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- SNPH | c.*2003C>T | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- SNRNP48 | c.*307A>G | 3'UTR (SNP) | VAF 27/35 reads (77%) | called by muse, mutect2, varscan2
- SOX21 | c.*113A>G | 3'UTR (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- TECRL | chr4:64276156 A>G | 3'Flank (SNP) | VAF 60/87 reads (69%) | called by muse, mutect2, varscan2
- TMEM132B | c.*143A>G | 3'UTR (SNP) | VAF 41/72 reads (57%) | called by muse, mutect2, varscan2
- TMEM237 | c.*3008C>T | 3'UTR (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- TRPM2 | c.-100-105G>A | Intron (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- UBN1 | c.-32G>A | 5'UTR (SNP) | VAF 58/199 reads (29%) | catalogued as rs778661217; called by muse, mutect2, varscan2
- UBXN2B | c.*2530T>A | 3'UTR (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- UQCRC1 | chr3:48609796 T>G | 5'Flank (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- WWTR1 | c.-108+1284T>G | Intron (SNP) | VAF 39/66 reads (59%) | called by muse, mutect2, varscan2
- XRN2 | c.*250T>G | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- ZBBX | c.1880-6468G>C | Intron (SNP) | VAF 49/159 reads (31%) | called by muse, mutect2, varscan2
